Surgical pathology report (de-identified scan), TCGA case TCGA-CR-5248, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-5248-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Accession Number: [REDACTED]

Final Report

DIAGNOSIS:

1) TONSIL, LEFT, TONSILLECTOMY: INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED.

2) FLOOR OF MOUTH, BIOPSY: SQUAMOUS MUCOSA WITH FOCAL FIBROSIS AND CHRONIC INFLAMMATION; NEGATIVE FOR MALIGNANCY OR DYSPLASIA.

Electronically signed by: [REDACTED]

CLINICAL DATA

Clinical Features/Dx: unspecified

Operator: [REDACTED]

Operation: unspecified

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: 1) left tonsil

GROSS DESCRIPTION:

1) SOURCE: Tonsil, Left. Received fresh are multiple small fragments of tan-white soft tissue, measuring in aggregate 1.5 x 1.0 x 0.4 cm. The fragments are not oriented. There is no normal tonsillar architecture present. A representative piece is submitted for research purposes. The entire remainder of the specimen is submitted for permanent section. Summary of sections: 1A, tonsil, 3/1.2)

SOURCE: Right base of Tongue. Received fresh are multiple fragments of tan-brown soft tissue, measuring in aggregate 2.3 x 1.2 x 0.5 cm. The specimen is entirely submitted. Summary of sections: 2A, right base of tongue, m/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

Date In Lab: [REDACTED]

[REDACTED]

[page 2 of 2]
[REDACTED]

Release of Information [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 54acf5be-a008-4716-8c2f-d76128333b90 (TCGA-CR-5248.CE631AF1-48D5-4333-8477-E05961E6FF04.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).